Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5RC, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5RC-01A (Primary Tumor).

Pathology Report for Tumor #

Diagnosis:

Anaplastic astrocytoma (WHO grade III)

MIB-1 labeling index= 8.6%

Discussion:

Numerous MIB-1 reactive cells are present throughout the tumor. In the most proliferation areas, a labeling index of 8.7 percent is calculated, consistent with a high grade tumor.

Microscopic Description:

Sections demonstrate a diffusely infiltrating astrocytic neoplasm. Hypercellularity varies from mild to marked. Atypia varies similarly. Numerous scattered mitotic figures are seen. No microvascular proliferation and no necrosis are seen.

ICD-O-3
Astrocytoma, anaplastic 9461/3
Site Path: Brain NOS C71.9
CGCR, Brain, Supratentorial C71.0
JW 2/27/13

fw 2/8/13
JW
2/5/13

Source: NCI Genomic Data Commons file b097311b-3ca3-4e61-95e3-9d9310708f27 (TCGA-HT-A5RC.A17D7270-D512-4F3F-B40C-588337E9222E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).